Gene-level copy-number profile of tumor specimen HTMCP-03-06-02128-01B from CGCI case HTMCP-03-06-02128, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G2; Age at diagnosis: 46.7 years (17,050 days).
Specimen HTMCP-03-06-02128-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a9873ccc-fb22-4ca1-a4d7-c4905a4ab339.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02128-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/1e4ed2a8-61f6-4f37-aec6-150ed20ca520

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 49; copy number 2: 12,885; copy number 3: 7,338; copy number 4: 32,145; copy number 5: 496; copy number 6: 1,928; copy number 7: 1,885; copy number 8: 194; copy number 9: 693; copy number 10: 551; copy number 11: 128; copy number 12: 11; copy number 13: 62.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes: AC239859.5, RNA5SP533, AC239859.3.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr4:9,459,255–9,460,244, 1 gene: OR7E86P.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr10:87,201,647–87,342,612, 4 genes (within-gene range 0–2): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A.
- chr10:87,504,875–88,049,823, 15 genes: MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,445 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–198,123,232, 631 genes, copy number 9–10 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 10: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 10: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 10 (within-gene range 4–10): TRGV5P, TRGV5, TRGV4.
- chr8:39,451,045–40,172,612, 16 genes, copy number 9: ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:41,509,593–41,578,421, 1 gene, copy number 9 (within-gene range 7–9): AC009630.1.
- chr8:41,566,858–43,674,591, 68 genes, copy number 9 (broad region; genes not listed).
- chr8:101,686,542–145,066,685, 635 genes, copy number 10–11 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 12: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:22,163,238–22,513,998, 61 genes, copy number 13 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 13: TRAC.
- chr15:101,922,042–101,979,093, 9 genes, copy number 9–12: OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
